Gene-level copy-number profile of specimen HCM-CSHL-0057-C18-85B from HCMI case HCM-CSHL-0057-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: GB; Age at diagnosis: 68.4 years (24,973 days).
Specimen HCM-CSHL-0057-C18-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7c223e23-5707-48ce-8abb-9d80566644f6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0057-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/6897c328-cfa3-4639-b50d-42fbfcda4a10

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 511; copy number 2: 18; copy number 3: 465; copy number 4: 34,321; copy number 5: 597; copy number 6: 13,788; copy number 7: 2,842; copy number 8: 5,133; copy number 9: 456; copy number 10: 374; copy number 11: 143; copy number 12: 175; copy number 13: 2; copy number 22: 1; copy number 24: 27; copy number 26: 6; copy number 27: 8; copy number 28: 4; copy number 29: 2; copy number 30: 7; copy number 31: 3; copy number 32: 3; copy number 34: 1; copy number 40: 8; copy number 41: 1; copy number 42: 4; copy number 43: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,229 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:6,490,793–8,344,516, 51 genes, copy number 9: AC072052.1, GRID2IP, ZDHHC4, AC079742.1, C7orf26, ZNF853, ZNF316, AC073343.2, AC073343.1, ZNF12, PMS2CL, SPDYE20P, RSPH10B2, CCZ1B, OR7E39P, UNC93B2, OR7E136P, OR7E59P, AC079804.2, ALG1L5P, AC079804.1, FAM86LP, AC079804.3, MIR3683, AC092104.1, Y_RNA, C1GALT1, AC005532.2, AC005532.1, AC079448.1, COL28A1, AC004982.1, AC004982.2, MIOS, AC004948.1, RPA3, UMAD1, AC007161.3, AC007161.2, AC007161.1, RNU6-534P, CCNB2P1, AC006042.3, GLCCI1-DT, GLCCI1, AC006042.2, ICA1, AC006042.1, AC007009.1, AC007128.1, AC007128.2.
- chr7:63,011,463–63,011,569, 1 gene, copy number 9: RNU6-417P.
- chr13:57,991,350–57,991,464, 1 gene, copy number 10: RNA5SP30.
- chr13:95,578,202–95,794,988, 7 genes, copy number 10 (within-gene range 8–10): DZIP1, DNAJC3-DT, DNAJC3, MTND5P2, MTND6P18, MTCYBP3, AL138955.1.
- chr16:29,905,012–31,917,357, 172 genes, copy number 9–12 (within-gene range 7–12) (broad region; genes not listed).
- chr16:46,469,341–46,689,518, 11 genes, copy number 9: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3.
- chr16:48,620,319–53,703,938, 118 genes, copy number 10–43 (within-gene range 10–47) (broad region; genes not listed).
- chr20:22,371,216–22,471,557, 1 gene, copy number 10: AL133464.1.
- chr20:30,214,765–64,327,972, 867 genes, copy number 9–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
